Somatic mutation profile of tumor specimen TCGA-DB-A64V-01A (aliquot TCGA-DB-A64V-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64V, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 54.6 years (19,950 days).
Specimen TCGA-DB-A64V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3d985e3-637f-426b-989c-f823d93f44de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64V-10A (Blood Derived Normal), aliquot TCGA-DB-A64V-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8e57224-6f2a-4672-a4ad-7b554b62ac62

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP9A | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as rs955672761, COSV58765261; called by muse, mutect2, varscan2
- BEND2 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV66220501; called by muse, mutect2, varscan2
- CIC | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50558428; called by muse, mutect2, varscan2
- CNGB3 | c.1009T>C p.F337L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60688106; called by muse, mutect2, varscan2
- COL19A1 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.339); catalogued as COSV100507873; called by muse, mutect2
- DOCK2 | c.3140T>C p.F1047S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56953302; called by muse, mutect2
- FUBP1 | c.735+2T>C p.X245_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV53929306; called by muse, mutect2, varscan2
- HAUS1 | c.474A>G p.Q158= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as COSV56363172; called by muse, mutect2, varscan2
- LTBP2 | c.2716G>A p.V906M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs1394883681, COSV56206961; called by muse, mutect2
- NACC1 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52834381, COSV52834842; called by muse, mutect2
- NEUROG3 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54342643; called by muse, mutect2
- OR10X1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1422494527, COSV63767248; called by muse, mutect2, varscan2
- PCDHGC5 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV52749145; called by muse, mutect2, varscan2
- PIKFYVE | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV52239745; called by muse, mutect2, varscan2
- POLR1A | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV55691798; called by muse, mutect2
- SART3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.429); catalogued as rs760281519, COSV57206701; called by muse, mutect2, varscan2
- SNRNP200 | c.2741A>G p.K914R | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs776940125, COSV60489118; called by muse, mutect2, varscan2
- USP53 | c.1676A>G p.D559G | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV56793758; called by muse, mutect2, varscan2
- ZBTB20 | c.1875G>C p.M625I (on ENST00000474710 / NM_001164342.2; = p.M552I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV61847845; called by muse, mutect2, varscan2
- GPANK1 | c.1012_1015del p.E338Rfs*10 | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by pindel, varscan2
- SAMD9L | c.1647_1663del p.L550Pfs*7 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ABCC9 | c.2436G>T p.L812= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV53968151, COSV53987468; called by muse, mutect2, varscan2
- BICD2 | c.1398G>A p.Q466= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV63548695; called by muse, mutect2, varscan2
- EP300 | c.4353T>C p.H1451= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs373752539, COSV54340565; called by muse, mutect2, varscan2
- FLNB | c.3999C>T p.A1333= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV55876493; called by muse, mutect2
- GJC1 | c.1182C>T p.V394= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV57911027; called by muse, mutect2, varscan2
- ZNF445 | c.219G>A p.L73= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV68538754; called by muse, mutect2
